Gene-level copy-number profile of specimen HCM-SANG-1332-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1332-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1332-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 81de16b0-16c4-4a33-b6ea-e0962cbdb78f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1332-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/e5bb9779-b114-4f3f-a294-ce7ff7a8ea02

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 54; copy number 2: 9,919; copy number 3: 19,600; copy number 4: 21,112; copy number 5: 4,130; copy number 6: 1,637; copy number 7: 1,023; copy number 8: 661; copy number 9: 729; copy number 10: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr14:18,967,434–19,003,752, 3 genes: POTEM, AL929601.3, RNU6-1239P.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 731 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,867,856–196,934,714, 1 gene, copy number 10 (within-gene range 6–10): SENP5.
- chr13:49,247,925–114,337,626, 730 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
